Somatic mutation profile of tumor specimen TCGA-VN-A88Q-01A (aliquot TCGA-VN-A88Q-01A-11D-A34U-08) from TCGA case TCGA-VN-A88Q, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 60.5 years (22,087 days).
Specimen TCGA-VN-A88Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a808f465-bbec-4b02-8edf-72f5f09fbf07.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VN-A88Q-10A (Blood Derived Normal), aliquot TCGA-VN-A88Q-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f04a106d-a748-47d9-809c-e5a7f4b71219

The open-access MAF lists 39 somatic variants for this specimen: 30 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 8, Nonsense Mutation 1, Splice Site 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALS2CL | c.1489G>A p.V497I | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV100015302; called by muse, mutect2, varscan2
- ARRDC3 | c.692C>T p.T231I | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.334); catalogued as rs751733629, COSV99475394; called by muse, mutect2, varscan2
- C3orf18 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.311); catalogued as rs777384605, COSV99231915; called by muse, mutect2, varscan2
- CCDC39 | c.437G>T p.W146L | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV99870580; called by muse, mutect2, varscan2
- CFAP70 | c.2308C>T p.R770W | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs141991496; called by muse, mutect2, varscan2
- CYTH4 | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99958147; called by muse, mutect2, varscan2
- DAPK1 | c.1300A>G p.N434D | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.027); catalogued as COSV100802707; called by muse, mutect2, varscan2
- GABRA4 | c.685C>A p.Q229K | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as rs75640222, COSV51936333, COSV99974661; called by muse, mutect2
- IL1RL1 | c.1346C>T p.T449I | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99294501; called by muse, mutect2, varscan2
- KDM5D | c.2776G>A p.A926T | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.438); catalogued as COSV100522306; called by muse, varscan2
- KLHL10 | c.1273G>A p.D425N | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99509673; called by muse, mutect2, varscan2
- KMT2E | c.2888G>A p.R963H | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.53); catalogued as rs370198555; called by muse, mutect2, varscan2
- LRP1B | c.11651-2A>T p.X3884_splice | Splice Site (SNP) | VAF 21/98 reads (21%) | catalogued as COSV101260569; called by muse, mutect2, varscan2
- OTOF | c.3641G>A p.R1214H (on ENST00000272371 / NM_194248.3; = p.R467H on NM_004802.4) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751557477, COSV55500285; called by muse, mutect2, varscan2
- PARP1 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 76/306 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1384102435, COSV64689588; called by muse, mutect2, varscan2
- PLEKHH2 | c.3256C>T p.R1086C | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765269949, COSV56754399; called by muse, mutect2, varscan2
- PTPN18 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs377115203, COSV51558247; called by muse, mutect2, varscan2
- RO60 | c.877G>A p.V293I | Missense Mutation (SNP) | VAF 62/245 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.282); catalogued as COSV100814433; called by muse, mutect2, varscan2
- RYR2 | c.1558C>T p.R520* | Nonsense Mutation (SNP) | VAF 34/104 reads (33%) | catalogued as rs749567039, COSV63662584, COSV63694540; called by muse, mutect2, varscan2
- RYR2 | c.12209C>T p.A4070V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.218); catalogued as rs777939821, COSV63699840; called by muse, mutect2, varscan2
- SH3RF1 | c.1228C>T p.L410F | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV99499476; called by muse, mutect2
- SLC41A1 | c.701T>C p.M234T | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs1177093217, COSV100900492; called by muse, mutect2, varscan2
- SRSF8 | c.520C>A p.P174T | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); catalogued as COSV101475822; called by mutect2, varscan2
- TAF1L | c.3754C>T p.R1252W | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54259076; called by muse, mutect2, varscan2
- TMEM132D | c.2631C>G p.H877Q | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.192); catalogued as COSV101243076; called by muse, mutect2, varscan2
- TOX4 | c.26A>G p.N9S | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as COSV99398585; called by muse, mutect2, varscan2
- TPTE2 | c.621A>C p.E207D (on ENST00000400230 / NM_199254.2; = p.E130D on NM_130785.3) | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.927); catalogued as COSV99690925; called by muse, mutect2, varscan2
- ZMIZ2 | c.2726A>G p.N909S | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748709917, COSV99537180; called by muse, mutect2, varscan2
- ZNF883 | c.481A>C p.T161P | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV101432688; called by muse, mutect2, varscan2
- NUP160 | c.682del p.L228Cfs*30 | Frame Shift Del (DEL) | VAF 27/102 reads (26%) | called by mutect2, pindel, varscan2
- KCNK4 | c.237G>A p.S79= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs371707971; called by muse, mutect2, varscan2
- MUC5B | c.558C>T p.N186= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs370483469; called by muse, mutect2, varscan2
- NEUROD2 | c.300G>T p.R100= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV100223204; called by muse, mutect2, varscan2
- OR2D2 | c.336C>T p.C112= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as rs140944764, COSV55057904; called by muse, mutect2, varscan2
- WDR7 | c.3348T>C p.S1116= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as rs1345382340, COSV99590382; called by muse, mutect2, varscan2
- XDH | c.3693G>A p.P1231= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs201405596, COSV65151867; called by muse, mutect2, varscan2
- ZNF365 | c.621A>G p.K207= | Silent (SNP) | VAF 35/132 reads (27%) | catalogued as COSV101237990; called by muse, mutect2, varscan2
- ZSCAN4 | c.72G>A p.A24= | Silent (SNP) | VAF 43/108 reads (40%) | catalogued as rs367836558; called by muse, mutect2, varscan2
- SLC7A2 | c.-22-4426C>T | Intron (SNP) | VAF 37/148 reads (25%) | catalogued as rs1366514120, COSV50257917; called by muse, mutect2, varscan2
